Somatic mutation profile of tumor specimen TCGA-78-7146-01A (aliquot TCGA-78-7146-01A-11D-2036-08) from TCGA case TCGA-78-7146, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.9 years (26,272 days).
Specimen TCGA-78-7146-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c714f92e-558d-4f85-8994-7382693f7cdf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7146-10A (Blood Derived Normal), aliquot TCGA-78-7146-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a594321c-a1aa-45c7-8460-ee554b75c97e

The open-access MAF lists 394 somatic variants for this specimen: 293 protein-altering or splice-affecting, 87 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 87, Nonsense Mutation 11, Frame Shift Del 8, Intron 5, RNA 5, Splice Site 4, 5'Flank 3, Splice Region 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 56/98 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 38/59 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AARD | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100991957, COSV65600563; called by muse, mutect2
- ABCA10 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV52230850; called by muse, mutect2, varscan2
- ABCA7 | c.5415G>C p.Q1805H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV54033511, COSV99565676; called by muse, mutect2, varscan2
- ABCC4 | c.1991C>G p.S664C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV65319540; called by muse, mutect2, varscan2
- ADAD1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99635548; called by muse, mutect2, varscan2
- ADGRB3 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65424592; called by muse, mutect2, varscan2
- AHNAK | c.16417G>A p.G5473S | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57217054, COSV57234556; called by muse, mutect2, varscan2
- AIRE | c.1150C>G p.P384A | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.188); catalogued as COSV52397824; called by muse, mutect2, varscan2
- AKT1S1 | c.445G>A p.E149K (on ENST00000344175 / NM_001098633.4; = p.E169K on NM_032375.5) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs775351244, COSV59278555; called by muse, mutect2, varscan2
- ANO3 | c.1628A>G p.K543R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.963); catalogued as COSV56811793; called by muse, mutect2, varscan2
- ANO5 | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61091097; called by muse, mutect2, varscan2
- APBB1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV54981248; called by muse, mutect2, varscan2
- APBB3 | c.1460A>T p.*487Lext*9 (on ENST00000357560 / NM_133173.2; = p.*494Lext*9 on NM_006051.3) | Nonstop Mutation (SNP) | VAF 55/166 reads (33%) | catalogued as COSV60366621; called by muse, mutect2, varscan2
- APOL1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59870106; called by muse, mutect2
- ARAP2 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58293706; called by muse, mutect2, varscan2
- ARHGEF2 | c.725-1G>A p.X242_splice (on ENST00000361247 / NM_001162383.2; = p.X214_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/103 reads (11%) | catalogued as COSV58118166; called by muse, mutect2, varscan2
- ATP2B2 | c.1892C>A p.A631E (on ENST00000352432; = p.A597E on NM_001683.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs753859888, COSV59508911; called by muse, mutect2, varscan2
- ATP5F1C | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59622271, COSV59623180; called by muse, mutect2, varscan2
- AXDND1 | c.2198G>T p.S733I | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV62648992; called by muse, mutect2, varscan2
- BBS9 | c.330A>C p.G110= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV54190910; called by muse, mutect2
- BCL11B | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV61740358; called by muse, mutect2, varscan2
- BCOR | c.1248A>T p.Q416H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60720678; called by muse, mutect2, varscan2
- BEND7 | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.418); catalogued as COSV61991678; called by muse, mutect2, varscan2
- BOD1L1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50090994; called by muse, mutect2
- BRAP | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.147); catalogued as COSV59538888; called by muse, mutect2, varscan2
- BRWD3 | c.2519C>G p.P840R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as COSV100956504, COSV64754497; called by muse, mutect2, varscan2
- BTNL8 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV51462529; called by muse, mutect2
- C1orf141 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.05); catalogued as COSV100924331, COSV63993215; called by muse, mutect2, varscan2
- C2CD3 | c.5225G>C p.C1742S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV58090998, COSV58102854; called by muse, mutect2, varscan2
- C6 | c.2324T>A p.L775Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV54720694; called by muse, mutect2, varscan2
- CACNA1C | c.6140G>T p.G2047V (on ENST00000399634 / NM_001167625.1; = p.G1976V on NM_000719.7) | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.642); catalogued as COSV59781974; called by muse, mutect2, varscan2
- CCDC40 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV53905276; called by muse, mutect2, varscan2
- CCP110 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV66818312; called by muse, mutect2
- CD40 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs778017892, COSV64848350; called by muse, mutect2, varscan2
- CDR1 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as COSV100983403; called by muse, mutect2, varscan2
- CDR1 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100983404, COSV65163882; called by muse, mutect2, varscan2
- CENPB | c.1133C>G p.S378W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60150629; called by muse, mutect2
- CFAP65 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV58567191; called by muse, mutect2, varscan2
- CHAMP1 | c.1330G>T p.G444W | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV63523462; called by muse, mutect2, varscan2
- CHN1 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.537); catalogued as COSV69299189; called by muse, mutect2, varscan2
- CHODL | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs556962391, COSV54732660, COSV54735705; called by muse, mutect2, varscan2
- CHP2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs373586872; called by muse, mutect2, varscan2
- CHRAC1 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 85/130 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55270512; called by muse, mutect2, varscan2
- CLINT1 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV51629938; called by muse, mutect2, varscan2
- CNGB1 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51908154; called by muse, mutect2, varscan2
- CNP | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs202171457, COSV57270689; called by muse, mutect2, varscan2
- COL22A1 | c.2153C>A p.P718H | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1017868991, COSV57364927; called by muse, mutect2, varscan2
- COL22A1 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57338891, COSV57364937; called by muse, mutect2, varscan2
- COL6A3 | c.6263C>T p.P2088L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113896755; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CRTAC1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.938); catalogued as rs761416143, COSV54005836; called by mutect2, varscan2
- CRYGD | c.520T>A p.S174T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV52206305; called by muse, mutect2, varscan2
- CSH2 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 276/345 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs755978056, COSV100400366, COSV61080260; called by muse, mutect2, varscan2
- CSMD3 | c.10507G>T p.G3503C (on ENST00000297405 / NM_001363185.1; = p.G3334C on NM_052900.3) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52345963; called by muse, mutect2
- CSMD3 | c.8663G>A p.G2888E (on ENST00000297405 / NM_001363185.1; = p.G2719E on NM_052900.3) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52345979; called by muse, mutect2, varscan2
- CSNK1G2 | c.1005G>A p.P335= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs1483870170, COSV55339837; called by muse, mutect2, varscan2
- CT83 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64140874, COSV64141593; called by muse, mutect2, varscan2
- CYLD | c.1619G>T p.R540M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61097839; called by muse, mutect2, varscan2
- DCAF12L1 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV64422964; called by muse, mutect2, varscan2
- DDX60L | c.5024G>C p.R1675P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52712546, COSV52723736; called by muse, varscan2
- DENND2A | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as COSV52060679; called by muse, mutect2, varscan2
- DKK2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53404583; called by muse, mutect2, varscan2
- DMKN | c.1351C>G p.P451A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs766879863, COSV60090809; called by muse, mutect2, varscan2
- DNAH17 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV67762368; called by muse, mutect2, varscan2
- DNAH3 | c.7243C>A p.H2415N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54557957; called by muse, mutect2, varscan2
- DNAH3 | c.3720G>T p.K1240N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV54557982; called by muse, mutect2, varscan2
- DNAJC13 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV53459748, COSV99606312; called by muse, mutect2, varscan2
- DNM1 | c.2194T>C p.Y732H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV57856872; called by muse, mutect2, varscan2
- DQX1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66353733; called by muse, mutect2, varscan2
- DRGX | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV65137781; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.87A>C p.K29N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.489); catalogued as COSV51766729; called by muse, mutect2
- DUSP2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as rs751919546, COSV56620882; called by muse, mutect2, varscan2
- DVL1 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs749925669, COSV66680768; called by muse, varscan2
- DYNC2H1 | c.10944G>T p.W3648C | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108728, COSV62109186; called by muse, mutect2, varscan2
- EFNB2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55363310; called by muse, mutect2, varscan2
- EGLN3 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV51656541; called by muse, mutect2, varscan2
- ERICH3 | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV58621050; called by muse, mutect2, varscan2
- ETNPPL | c.862T>A p.C288S | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV56597957; called by muse, mutect2, varscan2
- F8 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM080330, COSV64279638; called by muse, mutect2, varscan2
- F8 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64279645; called by muse, mutect2, varscan2
- FAM214A | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.124); catalogued as COSV55927754; called by muse, mutect2, varscan2
- FAM47B | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs375492603, COSV61457204; called by muse, mutect2, varscan2
- FAM47C | c.2356C>A p.L786I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV63731038; called by muse, mutect2, varscan2
- FER1L6 | c.2704C>A p.L902M | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV67553315; called by muse, mutect2, varscan2
- FGD4 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56790474; called by muse, mutect2, varscan2
- FGD5 | c.1106C>A p.A369E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.334); catalogued as COSV53254458; called by muse, mutect2, varscan2
- FGF13 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1488814153, COSV59551256; called by muse, mutect2, varscan2
- FLNA | c.2695G>T p.A899S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV61053286; called by muse, mutect2, varscan2
- FOXD4L1 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 102/514 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52077013; called by muse, mutect2, varscan2
- FREM1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as COSV66528474, COSV66531750; called by muse, mutect2, varscan2
- FSTL5 | c.1758C>G p.I586M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs1436541460, COSV60236525; called by muse, mutect2, varscan2
- FSTL5 | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV100054888; called by muse, mutect2, varscan2
- FSTL5 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100054891; called by muse, mutect2, varscan2
- GJB4 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1375118836, COSV58357266; called by muse, mutect2, varscan2
- GJB7 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746588765, COSV51531957; called by muse, mutect2, varscan2
- GLIPR1L1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56880283; called by muse, mutect2, varscan2
- GPR156 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV59942885; called by muse, mutect2, varscan2
- GPR162 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV50597083; called by muse, mutect2, varscan2
- GPR32 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54515861; called by muse, mutect2, varscan2
- GPR63 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57744162; called by muse, mutect2, varscan2
- GPRIN3 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV60886732; called by muse, mutect2, varscan2
- GPRIN3 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60886740; called by muse, mutect2, varscan2
- GRIA4 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56923818; called by muse, mutect2, varscan2
- GSG1L | c.982G>A p.G328R (on ENST00000447459 / NM_001109763.2; = p.G173R on NM_144675.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66583178; called by muse, mutect2, varscan2
- GSTO2 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 41/52 reads (79%) | catalogued as COSV58537855; called by muse, mutect2, varscan2
- H3C3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV63550652, COSV63551431, COSV63551470; called by muse, mutect2, varscan2
- HCFC1 | c.2336C>A p.T779N | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV60078662; called by muse, mutect2, varscan2
- HCLS1 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164316904, COSV57528440; called by muse, mutect2, varscan2
- HEATR1 | c.4469G>T p.S1490I | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1469602488, COSV63983488; called by muse, mutect2, varscan2
- HFM1 | c.2772G>T p.W924C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54039012; called by muse, mutect2, varscan2
- HIVEP2 | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV50086557; called by muse, mutect2, varscan2
- HTR7 | c.404T>A p.M135K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53294048; called by mutect2, varscan2
- IFI16 | c.1210C>G p.L404V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV55541160; called by mutect2, varscan2
- IGSF10 | c.5515G>T p.A1839S | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV56793191; called by muse, mutect2, varscan2
- IL22RA2 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51665001; called by muse, mutect2, varscan2
- INPP4B | c.353A>T p.K118M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53749157; called by muse, mutect2, varscan2
- INTS6L | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66086770; called by muse, mutect2, varscan2
- IRAG2 | c.3873G>C p.M1291I (on ENST00000636465; = p.M336I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV57232301, COSV57237482; called by muse, mutect2, varscan2
- ITGA4 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); catalogued as COSV52005068; called by muse, mutect2, varscan2
- ITGAD | c.3316G>T p.G1106C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54932910; called by muse, mutect2, varscan2
- KARS1 | c.1013G>T p.C338F | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56694803; called by muse, mutect2, varscan2
- KDM5C | c.782-1G>C p.X261_splice | Splice Site (SNP) | VAF 31/77 reads (40%) | catalogued as COSV64770943; called by muse, mutect2, varscan2
- KEAP1 | c.1475del p.P492Qfs*8 | Frame Shift Del (DEL) | VAF 29/70 reads (41%) | catalogued as COSV99408188; called by mutect2, pindel, varscan2
- KIF21B | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1174051997, COSV59768411; called by muse, mutect2, varscan2
- KLHL1 | c.1921G>T p.G641* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV64786648; called by muse, mutect2, varscan2
- KLHL13 | c.1556C>A p.A519E | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV53245495, COSV53254066; called by muse, mutect2, varscan2
- KLHL18 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51749083; called by muse, mutect2, varscan2
- KMT2D | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs1488501817, COSV56493941; called by muse, mutect2, varscan2
- KRT39 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62918189; called by muse, mutect2, varscan2
- KRTAP6-3 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | PolyPhen benign (0.047); catalogued as COSV66962714, COSV66963464; called by muse, mutect2
- KRTAP6-3 | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | PolyPhen benign (0.035); catalogued as COSV66963468; called by muse, mutect2
- LCT | c.1519C>A p.H507N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as COSV51558865; called by muse, mutect2, varscan2
- LCT | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51546571, COSV51558873; called by muse, mutect2, varscan2
- LDLR | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs769247787, COSV52946463; called by muse, mutect2, varscan2
- LNPK | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55826792; called by muse, mutect2, varscan2
- LPAR6 | c.690G>C p.M230I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57330197; called by muse, mutect2, varscan2
- LRRTM3 | c.1606C>G p.H536D | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV63673018; called by muse, mutect2, varscan2
- MAGEA1 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); catalogued as COSV63118192, COSV63119393; called by muse, mutect2
- MAGEB1 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV66776782; called by muse, mutect2, varscan2
- MAGEC3 | c.1517A>C p.E506A | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV68924447; called by muse, mutect2, varscan2
- MAGED2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.593); catalogued as rs779634966, COSV54497890; called by muse, mutect2, varscan2
- MARCHF7 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52029984, COSV52032004; called by muse, mutect2, varscan2
- MDN1 | c.9368C>T p.S3123L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65531920; called by muse, mutect2, varscan2
- MEFV | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54828679; called by muse, mutect2, varscan2
- MMP20 | c.644C>A p.T215K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs377682409, COSV52778914; called by muse, varscan2
- MPPED1 | c.940C>A p.P314T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV68839472; called by muse, mutect2, varscan2
- MRPL47 | c.64T>A p.S22T | Missense Mutation (SNP) | VAF 118/193 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52022023; called by muse, mutect2, varscan2
- MTBP | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV59967092; called by muse, mutect2, varscan2
- MTCL1 | c.3884G>T p.R1295L (on ENST00000306329 / NM_001378206.1; = p.R976L on NM_015210.4) | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1054270301, COSV60403626, COSV60409473, COSV60413105; called by muse, mutect2, varscan2
- MTRR | c.1557G>T p.W519C (on ENST00000264668; = p.W492C on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52947498; called by muse, mutect2, varscan2
- MYBPC1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62258384; called by muse, mutect2, varscan2
- MYO3A | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.069); catalogued as COSV56352650; called by muse, mutect2, varscan2
- NAV3 | c.5336G>T p.G1779V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57117288; called by muse, mutect2, varscan2
- NBAS | c.2893G>T p.D965Y | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55740924; called by muse, mutect2, varscan2
- NELL1 | c.1009T>A p.Y337N | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100126137, COSV54335967; called by muse, mutect2, varscan2
- NEO1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV56079229; called by muse, mutect2, varscan2
- NEUROD2 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.018); catalogued as rs1209262167, COSV56911953; called by muse, mutect2
- NF1 | c.5609+1G>T p.X1870_splice (on ENST00000358273 / NM_001042492.3; = p.X1849_splice on NM_000267.3) | Splice Site (SNP) | VAF 30/49 reads (61%) | catalogued as CS000879, CS072258, CS992457, COSV62194068, COSV62200690, COSV62224640; called by muse, mutect2, varscan2
- NIPAL4 | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV61731385; called by muse, mutect2, varscan2
- NLGN4X | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV52020762; called by muse, mutect2, varscan2
- NPIPA1 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60155230; called by muse, mutect2, varscan2
- NRL | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs752230175, COSV53745901, COSV99393645; called by muse, mutect2, varscan2
- NSG1 | c.288C>A p.C96* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV67575847; called by muse, mutect2, varscan2
- NTRK3 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58147995; called by muse, mutect2, varscan2
- OAS2 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV60804823; called by muse, mutect2, varscan2
- OGT | c.2758G>A p.V920I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV65482356; called by muse, mutect2, varscan2
- OLFML2A | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as COSV56585995; called by muse, mutect2, varscan2
- OLFML2B | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV54201111; called by muse, mutect2
- OR10A2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56300759; called by muse, mutect2, varscan2
- OR13C8 | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV100623028, COSV58612730; called by muse, mutect2, varscan2
- OR14K1 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99315076, COSV99315140; called by muse, mutect2, varscan2
- OR2A2 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68872683; called by muse, mutect2, varscan2
- OR2G3 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV60683564; called by muse, mutect2, varscan2
- OR2H1 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV65811598; called by muse, mutect2, varscan2
- OR4C15 | c.346T>A p.L116M (on ENST00000314644; = p.L62M on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2, varscan2
- OR4C46 | c.826A>T p.I276L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); catalogued as COSV60221572; called by muse, mutect2, varscan2
- OR51V1 | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58316656; called by muse, mutect2, varscan2
- OR5L2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65723659, COSV65725420; called by muse, mutect2, varscan2
- OR8H2 | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 182/418 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV57947869; called by muse, mutect2, varscan2
- OSR1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV55346746; called by muse, mutect2, varscan2
- OSR2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV52559461, COSV99882619; called by muse, mutect2, varscan2
- PAPOLB | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV68200221, COSV68202067; called by muse, mutect2, varscan2
- PAX8 | c.656C>A p.P219H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV54508493; called by muse, mutect2, varscan2
- PCDHB11 | c.1826C>A p.A609D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.698); catalogued as rs529417774; called by muse, varscan2
- PCDHB15 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.222); catalogued as COSV51427582; called by muse, mutect2, varscan2
- PCDHGA5 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.195); catalogued as rs188773052, COSV54007929, COSV54051186; called by muse, mutect2, varscan2
- PDCD6IP | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1446289137, COSV56244248, COSV56246361; called by muse, mutect2, varscan2
- PDE3A | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62969798; called by muse, mutect2, varscan2
- PDZD4 | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.991); catalogued as COSV51252694; called by muse, mutect2, varscan2
- PER2 | c.1501A>T p.S501C | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54528785; called by muse, mutect2, varscan2
- PER2 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV54528800; called by muse, mutect2, varscan2
- PIANP | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV57708612; called by muse, mutect2, varscan2
- PIPOX | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as rs773849011, COSV60144053; called by muse, mutect2, varscan2
- PIWIL4 | c.237C>G p.D79E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV54413151; called by muse, mutect2, varscan2
- PLA2G4A | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV100820524; called by muse, mutect2, varscan2
- PLA2G4A | c.1127C>A p.T376K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV100820525; called by muse, mutect2, varscan2
- PLXNB3 | c.2133C>A p.F711L | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62796431, COSV62803129; called by muse, mutect2, varscan2
- POLR1B | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54504574; called by muse, mutect2, varscan2
- POTEM | c.1036del p.V346Ffs*7 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as COSV101193810; called by mutect2, varscan2
- PTGER3 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100656840; called by mutect2, varscan2
- PXDN | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570640127, COSV53237614, COSV99412394; called by muse, mutect2, varscan2
- PXDNL | c.927T>A p.N309K | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV62500673; called by muse, mutect2, varscan2
- RAB27B | c.176A>T p.N59I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV50496769; called by muse, mutect2, varscan2
- RALGAPA1 | c.4285A>G p.I1429V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1566885920, COSV51899638; called by muse, mutect2, varscan2
- RECQL | c.631A>T p.R211W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV59084962, COSV59086127; called by muse, mutect2, varscan2
- RET | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.833); catalogued as CM000030, COSV60710761; called by muse, mutect2, varscan2
- RIMS2 | c.4572G>T p.W1524C (on ENST00000666250 / NM_001348490.2; = p.W1095C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51731939; called by muse, mutect2, varscan2
- RP1L1 | c.6373G>T p.A2125S | Missense Mutation (SNP) | VAF 148/350 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.065); catalogued as COSV101223195; called by muse, mutect2, varscan2
- RP1L1 | c.6372G>T p.E2124D | Missense Mutation (SNP) | VAF 149/348 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101223197; called by muse, mutect2, varscan2
- RPTN | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 82/714 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV60169582; called by muse, varscan2
- RSC1A1 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV60781833; called by muse, mutect2, varscan2
- RSPO1 | c.529C>A p.R177S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs764878797, COSV100740649, COSV62975593; called by muse, mutect2, varscan2
- RYR3 | c.10422G>T p.W3474C (on ENST00000389232; = p.W3475C on NM_001036.6) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66811077; called by muse, mutect2, varscan2
- SAGE1 | c.2389G>T p.D797Y | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61019073; called by muse, mutect2, varscan2
- SALL4 | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV53856797; called by muse, mutect2, varscan2
- SCRIB | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57594598; called by muse, mutect2
- SERPINE2 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV51460622; called by muse, mutect2, varscan2
- SHQ1 | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57768806; called by muse, mutect2, varscan2
- SLAIN2 | c.1019A>C p.N340T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV51911173; called by muse, varscan2
- SLC25A40 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62022048; called by muse, mutect2, varscan2
- SLC45A3 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65655725; called by muse, mutect2, varscan2
- SLC5A10 | c.1238G>C p.G413A (on ENST00000395645 / NM_001042450.4; = p.G429A on NM_152351.5) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV58762915; called by muse, varscan2
- SLITRK1 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV65678046; called by muse, mutect2, varscan2
- SLITRK3 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53854436; called by muse, mutect2, varscan2
- SMPD4 | c.2029A>T p.R677W (on ENST00000409031 / NM_017951.4; = p.R648W on NM_017751.4) | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV60083362; called by muse, varscan2
- SNTG1 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52478194, COSV99384461; called by muse, mutect2, varscan2
- SPATA46 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 59/438 reads (13%) | catalogued as COSV62633424, COSV62641057; called by muse, mutect2, varscan2
- SPTBN1 | c.5764G>A p.D1922N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61689464, COSV61695319; called by muse, mutect2, varscan2
- SPTLC2 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV53642876, COSV53643744; called by muse, mutect2, varscan2
- SRBD1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.76); catalogued as rs1484909711, COSV55400245; called by muse, mutect2, varscan2
- ST8SIA2 | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 54/67 reads (81%) | PolyPhen benign (0.005); catalogued as COSV51573805; called by muse, mutect2, varscan2
- SUPT6H | c.2887A>G p.I963V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.067); catalogued as COSV58931025; called by muse, mutect2, varscan2
- TANC2 | c.3596G>A p.G1199E | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV67342844; called by muse, mutect2, varscan2
- TBC1D19 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53522657; called by muse, mutect2, varscan2
- TDO2 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70809890; called by muse, varscan2
- TENM1 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.099); catalogued as COSV64446409; called by muse, mutect2, varscan2
- TENM1 | c.326C>A p.T109K | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64426995, COSV64446421; called by muse, mutect2, varscan2
- TEX15 | c.5402C>A p.S1801Y (on ENST00000256246; = p.S2184Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs1369385416, COSV56345421, COSV56355535; called by muse, mutect2, varscan2
- TFAP4 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.546); catalogued as COSV52599324; called by muse, mutect2, varscan2
- TG | c.3032C>T p.S1011F | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as COSV55097443; called by muse, mutect2, varscan2
- THSD7B | c.3385G>A p.E1129K (on ENST00000272643; = p.E1127K on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV55746483; called by muse, mutect2, varscan2
- TIMD4 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV50861995; called by muse, mutect2, varscan2
- TMEM144 | c.889A>G p.I297V | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as COSV56703370; called by muse, mutect2, varscan2
- TMEM196 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68256875; called by muse, mutect2, varscan2
- TMEM255B | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100943159, COSV64703697, COSV64705055; called by muse, mutect2, varscan2
- TMEM255B | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV64715239; called by muse, mutect2, varscan2
- TNN | c.2207A>G p.D736G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53437712; called by muse, varscan2
- TNPO2 | c.1609A>T p.I537F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV63510610; called by muse, mutect2, varscan2
- TOPBP1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV53443060; called by muse, mutect2, varscan2
- TPK1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100766029, COSV63650034; called by muse, mutect2, varscan2
- TRPS1 | c.3515G>T p.R1172I (on ENST00000220888 / NM_001330599.2; = p.R1185I on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV55266168; called by muse, mutect2, varscan2
- TSHZ2 | c.217C>G p.H73D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.574); catalogued as COSV61592322; called by muse, mutect2, varscan2
- TTLL1 | c.1213G>T p.G405W | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV56741093; called by muse, mutect2, varscan2
- TTN | c.57857G>A p.R19286H (on ENST00000591111; = p.R11862H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | PolyPhen benign (0.017); catalogued as rs397517652, COSV59949524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.10666G>A p.D3556N (on ENST00000591111; = p.D3510N on NM_003319.4) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | catalogued as COSV60404607; called by muse, mutect2, varscan2
- TUBA3D | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as rs1284864122, COSV58310568; called by muse, varscan2
- TWF1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57302296; called by muse, mutect2, varscan2
- UBA6 | c.2159A>G p.H720R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV59181489; called by muse, mutect2, varscan2
- UBE2A | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60636064, COSV60637323; called by muse, mutect2, varscan2
- UQCC1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62903914; called by muse, mutect2, varscan2
- USH2A | c.13060G>T p.A4354S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); catalogued as rs757373033, COSV56451171; called by muse, mutect2, varscan2
- USP31 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54858478; called by muse, mutect2, varscan2
- VCAM1 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV54122814; called by muse, mutect2, varscan2
- VCAN | c.3760T>A p.S1254T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54119012; called by muse, mutect2, varscan2
- VPS72 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 331/477 reads (69%) | catalogued as rs1268145999, COSV63168396; called by muse, mutect2, varscan2
- XPNPEP2 | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV64368282; called by muse, mutect2, varscan2
- XXYLT1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs186038785, COSV59987329; called by muse, mutect2, varscan2
- ZBTB11 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV57247331; called by muse, mutect2, varscan2
- ZBTB24 | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 71/99 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV57784173; called by muse, mutect2, varscan2
- ZEB1 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58056899; called by muse, mutect2, varscan2
- ZFHX4 | c.9847C>T p.Q3283* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | catalogued as COSV50644280, COSV51501047; called by muse, mutect2, varscan2
- ZFPM2 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV101023257, COSV65875262; called by muse, mutect2, varscan2
- ZKSCAN2 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV60159206; called by muse, mutect2, varscan2
- ZKSCAN8 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57640584; called by muse, mutect2, varscan2
- ZNF37A | c.1392G>C p.E464D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV61073515, COSV61075985; called by muse, mutect2, varscan2
- ZNF449 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59348363; called by muse, mutect2, varscan2
- ZNF70 | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV59534223; called by muse, mutect2, varscan2
- ZP3 | c.703G>T p.D235Y (on ENST00000394857 / NM_001110354.2; = p.D184Y on NM_007155.6) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60636087; called by muse, mutect2, varscan2
- ZSCAN5A | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs748809925, COSV54226890, COSV54228118; called by muse, mutect2, varscan2
- ZZEF1 | c.3076T>G p.C1026G | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV67560728; called by muse, mutect2, varscan2
- ABCB11 | c.3444_3462del p.N1148Kfs*17 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP6 | c.1667_1681del p.T556_P560del | In Frame Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- CSMD2 | c.8474del p.P2825Lfs*32 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by pindel, varscan2
- EPHX1 | c.189dup p.H64Tfs*6 | Frame Shift Ins (INS) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- HOXA1 | c.769_770del p.A257Pfs*31 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | called by pindel, varscan2
- MAGEA9B | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by mutect2, varscan2
- MAGEB6B | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MCMDC2 | c.285+2dup p.X95_splice | Splice Site (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- NLRP1 | c.973del p.Q325Kfs*5 | Frame Shift Del (DEL) | VAF 111/219 reads (51%) | called by mutect2, pindel, varscan2
- NPTX2 | c.1185del p.T396Qfs*103 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- POTED | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.167); called by mutect2, varscan2
- ZNF804B | c.1763del p.L588Qfs*31 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- ADAM11 | c.1095G>A p.A365= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52346115; called by muse, mutect2, varscan2
- ADGRB1 | c.2580G>A p.P860= | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as rs377353688, COSV60096316; called by muse, mutect2, varscan2
- AKT2 | c.609C>T p.V203= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as rs1181181846, COSV60910739; called by muse, mutect2, varscan2
- ALAS2 | c.546T>A p.S182= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV58193871; called by muse, mutect2, varscan2
- C6orf118 | c.774G>A p.T258= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as rs376983039, COSV57820355; called by muse, mutect2, varscan2
- CALML3 | c.201C>T p.P67= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100178805, COSV59449246, COSV59449298; called by muse, mutect2, varscan2
- CASR | c.789G>A p.T263= | Silent (SNP) | VAF 132/202 reads (65%) | catalogued as rs369124816, COSV56142135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCM2 | c.978C>A p.R326= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV51851874; called by muse, mutect2, varscan2
- CDH23 | c.6237A>G p.L2079= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV56494619; called by muse, mutect2, varscan2
- CDX4 | c.402G>T p.G134= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV65171973; called by muse, mutect2, varscan2
- CELA3A | c.660C>A p.P220= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as COSV51587592; called by muse, mutect2, varscan2
- CENPN | c.825C>T p.F275= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV59905646; called by muse, mutect2
- CFAP54 | c.5967C>A p.G1989= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV61570802, COSV61576031; called by muse, mutect2, varscan2
- CIP2A | c.72G>C p.A24= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV55421783; called by muse, mutect2
- CLTC | c.54G>C p.L18= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV52253967; called by muse, mutect2, varscan2
- CNTN6 | c.2154C>A p.V718= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV63191006, COSV63192882; called by muse, mutect2, varscan2
- COL6A3 | c.6264G>T p.P2088= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV55079579, COSV99797960; called by muse, mutect2, varscan2
- CPQ | c.609C>A p.L203= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV55164136; called by muse, mutect2
- DNAH17 | c.1698G>A p.Q566= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV67762362; called by muse, mutect2, varscan2
- DNAH3 | c.7470C>T p.L2490= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54557940; called by muse, mutect2, varscan2
- DSG3 | c.2484G>T p.V828= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV57130292; called by muse, mutect2, varscan2
- EBF3 | c.1542C>A p.S514= (on ENST00000355311 / NM_001375392.1; = p.S505= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV62482933; called by muse, mutect2, varscan2
- EFHC1 | c.138G>C p.G46= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV64138093; called by muse, mutect2, varscan2
- ERGIC2 | c.762G>T p.V254= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV64113642; called by muse, mutect2, varscan2
- F8 | c.3375A>C p.A1125= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV64279632; called by muse, mutect2, varscan2
- FAM214A | c.1806G>A p.Q602= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV55927748; called by muse, mutect2, varscan2
- GABRA5 | c.213C>T p.R71= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV59486867; called by muse, mutect2, varscan2
- GDPD5 | c.1737T>C p.Y579= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs754882301, COSV61130775; called by muse, mutect2, varscan2
- GRIP1 | c.564A>T p.G188= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV54046286; called by muse, mutect2, varscan2
- GRM1 | c.492C>A p.S164= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV51375107; called by muse, mutect2, varscan2
- GRM6 | c.1707G>T p.T569= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV51434498, COSV51448132; called by muse, varscan2
- HAP1 | c.1665G>A p.T555= (on ENST00000310778 / NM_001367460.1; = p.T503= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/361 reads (24%) | catalogued as rs782272213, COSV57881239; called by muse, mutect2, varscan2
- HECTD1 | c.2694A>G p.V898= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV65991407; called by muse, mutect2, varscan2
- HEPHL1 | c.1608G>T p.L536= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59897509; called by muse, mutect2, varscan2
- HLA-DOA | c.450C>T p.N150= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs756316995, COSV57713460; called by muse, mutect2, varscan2
- HOXA9 | c.555C>A p.G185= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1048897054, COSV58656866; called by muse, mutect2, varscan2
- HSPA6 | c.537G>C p.T179= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs370722659; called by muse, mutect2
- JAKMIP1 | c.6G>A p.S2= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs774024893, COSV51547595; called by muse, mutect2, varscan2
- KALRN | c.1587G>A p.K529= | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as COSV53782792; called by muse, mutect2, varscan2
- KIF3B | c.555G>A p.K185= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV65227310, COSV65229629; called by muse, mutect2, varscan2
- KIFAP3 | c.2325C>A p.A775= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV63038004; called by muse, mutect2
- LLGL1 | c.1107G>T p.L369= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV57501434; called by muse, mutect2, varscan2
- LRATD1 | c.141C>A p.R47= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1212685796, COSV54474549; called by muse, mutect2, varscan2
- MFSD2A | c.1282C>T p.L428= (on ENST00000372809 / NM_001136493.3; = p.L415= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV65686771; called by muse, mutect2, varscan2
- MROH9 | c.144G>C p.V48= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV63013522; called by muse, mutect2, varscan2
- MTG1 | c.246C>T p.L82= | Silent (SNP) | VAF 108/216 reads (50%) | catalogued as COSV53375322; called by muse, mutect2, varscan2
- MUC5B | c.8352C>A p.I2784= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV101500283; called by muse, mutect2, varscan2
- MXRA5 | c.369C>T p.L123= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54232249; called by muse, mutect2, varscan2
- NAT10 | c.828G>A p.L276= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs771936992, COSV57666676; called by muse, mutect2, varscan2
- NEIL3 | c.126C>A p.L42= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV52814334, COSV99220169; called by muse, mutect2, varscan2
- NFATC2IP | c.987C>T p.I329= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV57911551; called by muse, mutect2, varscan2
- NIN | c.1506C>T p.N502= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV55409366; called by muse, mutect2, varscan2
- NLRP14 | c.516C>G p.T172= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100204677, COSV55073048; called by muse, mutect2, varscan2
- NLRP2 | c.2223T>A p.A741= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54761488; called by muse, mutect2, varscan2
- NSMAF | c.2175C>T p.N725= | Silent (SNP) | VAF 56/84 reads (67%) | catalogued as rs140144207; called by muse, mutect2, varscan2
- NYAP1 | c.1069C>T p.L357= | Silent (SNP) | VAF 99/147 reads (67%) | catalogued as COSV55722666; called by muse, mutect2, varscan2
- OR12D3 | c.837C>A p.A279= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV65830889; called by muse, mutect2, varscan2
- OR4K17 | c.603C>T p.A201= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV59649264; called by muse, mutect2, varscan2
- OR51F2 | c.60A>T p.P20= | Silent (SNP) | VAF 46/275 reads (17%) | catalogued as COSV59066311; called by muse, mutect2, varscan2
- OR5H6 | c.813C>T p.L271= (on ENST00000642105; = p.L255= on NM_001005479.2) | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs1477764393, COSV67352198; called by muse, mutect2, varscan2
- OR5P2 | c.18C>T p.D6= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs140666195; called by muse, mutect2, varscan2
- PCDH15 | c.1746G>T p.T582= | Silent (SNP) | VAF 59/141 reads (42%) | catalogued as COSV57354390, COSV57408711; called by muse, mutect2, varscan2
- PCDH19 | c.489G>T p.V163= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV55273063; called by muse, mutect2, varscan2
- PCDHB14 | c.1425C>A p.A475= | Silent (SNP) | VAF 126/229 reads (55%) | catalogued as COSV53391821; called by muse, mutect2, varscan2
- PCDHGA6 | c.1236G>T p.R412= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV54025241, COSV54051204; called by muse, mutect2, varscan2
- PCDHGB4 | c.1932G>T p.V644= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV54051223; called by muse, mutect2, varscan2
- PCLO | c.4899C>T p.D1633= | Silent (SNP) | VAF 88/264 reads (33%) | catalogued as rs937578785, COSV61675277; called by muse, mutect2, varscan2
- PLEKHO1 | c.906G>A p.P302= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs587728777, COSV50311777; called by muse, mutect2, varscan2
- PLPPR4 | c.1764C>A p.V588= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV64567959; called by muse, mutect2, varscan2
- PPM1H | c.1437G>T p.R479= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV57380124; called by muse, varscan2
- PTPN21 | c.2440C>T p.L814= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV60852688; called by muse, mutect2, varscan2
- RADX | c.1956G>C p.P652= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV65320342; called by muse, mutect2, varscan2
- ROS1 | c.7017C>T p.H2339= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as COSV63862608; called by muse, mutect2, varscan2
- RTP1 | c.678G>T p.S226= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV56617535, COSV56619176; called by muse, mutect2, varscan2
- SLC8A3 | c.1560A>G p.T520= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs746948844, COSV63527592; called by muse, mutect2, varscan2
- SLCO5A1 | c.2193G>T p.V731= | Silent (SNP) | VAF 45/260 reads (17%) | catalogued as COSV52669926; called by muse, mutect2, varscan2
- SNRK | c.2121C>T p.F707= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs753178140, COSV56071547; called by muse, mutect2, varscan2
- STIL | c.1629T>C p.A543= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV54554556; called by muse, mutect2, varscan2
- STON2 | c.1368A>G p.A456= (on ENST00000649389 / NM_001366849.2; = p.A399= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV50857408; called by muse, mutect2, varscan2
- SVEP1 | c.10152T>C p.C3384= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV52845048; called by muse, mutect2, varscan2
- TNC | c.5478G>A p.V1826= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100405530, COSV60791706; called by muse, mutect2, varscan2
- TOMM20L | c.165G>A p.E55= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV62878586; called by muse, mutect2, varscan2
- UHRF1BP1L | c.648C>T p.I216= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1365952411, COSV54434533; called by muse, mutect2, varscan2
- WNT2 | c.9C>T p.A3= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55414364; called by muse, mutect2, varscan2
- XKR7 | c.1191G>A p.A397= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV73813529; called by muse, mutect2, varscan2
- ZIC5 | c.1503C>G p.V501= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV57439256, COSV57439407; called by muse, mutect2, varscan2
- ZNF619 | c.621G>A p.Q207= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs138484130, COSV59031657; called by muse, mutect2, varscan2
- AGAP7P | n.1441G>A | RNA (SNP) | VAF 13/56 reads (23%) | catalogued as rs1554941348; called by mutect2, varscan2
- AL590867.2 | n.318T>C | RNA (SNP) | VAF 80/112 reads (71%) | catalogued as rs755854174; called by muse, mutect2, varscan2
- AMACR | c.739+1338del | Intron (DEL) | VAF 40/251 reads (16%) | called by mutect2, pindel, varscan2
- CD300LD | chr17:74592595 C>A | 5'Flank (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- GCSH | chr16:81101237 G>C | 5'Flank (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- GSPT1 | c.-63+132C>T | Intron (SNP) | VAF 15/78 reads (19%) | catalogued as rs753594316, COSV101341722; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85566G>T | Intron (SNP) | VAF 15/63 reads (24%) | catalogued as COSV72284007; called by muse, mutect2, varscan2
- NXF5 | n.717A>T | RNA (SNP) | VAF 71/476 reads (15%) | catalogued as COSV99534345; called by muse, varscan2
- RPS12 | c.235-130T>C | Intron (SNP) | VAF 12/284 reads (4%) | catalogued as rs1300800205, COSV100016323; called by muse, mutect2
- SNORD115-5 | n.73G>T | RNA (SNP) | VAF 78/264 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.7026C>G | RNA (SNP) | VAF 28/74 reads (38%) | catalogued as COSV50489644; called by muse, mutect2, varscan2
- TRPV2 | chr17:16439291 C>T | 3'Flank (SNP) | VAF 31/78 reads (40%) | catalogued as rs772567328; called by muse, mutect2, varscan2
- WASHC2C | chr10:45722331 C>T | 5'Flank (SNP) | VAF 65/220 reads (30%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.945-384G>C | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100203437; called by muse, mutect2, varscan2
